Gene-level copy-number profile of tumor specimen TCGA-B7-A5TN-01A from TCGA case TCGA-B7-A5TN, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Fundus of stomach; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 60.1 years (21,962 days).
Specimen TCGA-B7-A5TN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.9f663144-960f-47df-b8f7-14f1bf052438.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-B7-A5TN-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3ea583d4-9248-4c3c-a352-70746e548f7d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 709; copy number 2: 25,318; copy number 3: 18,514; copy number 4: 7,291; copy number 5: 6,469; copy number 6: 1,269; copy number 7: 6; copy number 8: 22; copy number 9: 177; copy number 10: 19; copy number 42: 24.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-B7-A5TN-01A-21D-A31K-01): tumor purity 0.54, ploidy 2.75, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 7,599 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:28,736,621–29,496,893, 17 genes, copy number 5: YTHDF2, OPRD1, AL009181.1, Y_RNA, EPB41, AL138785.1, Y_RNA, Metazoa_SRP, TMEM200B, AL357500.1, SRSF4, AL357500.2, MECR, AL590729.1, PTPRU, LINC01756, AL671862.1.
- chr1:40,344,850–43,454,247, 106 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr1:156,147,366–157,191,963, 55 genes, copy number 6 (within-gene range 4–6): SEMA4A, AL135927.1, SLC25A44, PMF1-BGLAP, PMF1, BGLAP, PAQR6, SMG5, TMEM79, GLMP, VHLL, CCT3, TSACC, RHBG, AL139130.1, MIR9-1HG, MIR9-1, MEF2D, Y_RNA, AL365181.1, IQGAP3, TTC24, NAXE, GPATCH4, AL365181.4, HAPLN2, AL365181.2, BCAN, AL365181.3, AL590666.2, NES, AL590666.3, AL590666.4, CRABP2, AL590666.1, ISG20L2, RRNAD1, MRPL24, HDGF, PRCC, AL590666.5, SH2D2A, NTRK1, INSRR, PEAR1, LRRC71, ARHGEF11, MIR765, RN7SL612P, SMU1P1, KRT8P45, ETV3L, ETV3, CYCSP52, AL357143.1.
- chr1:160,932,465–161,728,143, 57 genes, copy number 5: AL354714.1, AL354714.4, ITLN2, F11R, AL591806.2, GLRX5P2, TSTD1, USF1, ARHGAP30, NECTIN4, NECTIN4-AS1, KLHDC9, PFDN2, NIT1, DEDD, AL591806.1, UFC1, AL590714.1, USP21, PPOX, B4GALT3, ADAMTS4, NDUFS2, FCER1G, APOA2, TOMM40L, MIR5187, NR1I3, PCP4L1, MPZ, SDHC, CFAP126, AL592295.6, RRM2P2, AL592295.4, AL592295.5, RNU6-481P, AL592295.3, AL592295.1, AL592295.2, AL831711.1, FCGR2A, AL590385.2, HSPA6, RPS23P10, FCGR3A, AL590385.1, FCGR2C, HSPA7, RPS23P9, FCGR3B, FCGR2B, AL451067.1, RPL31P11, Y_RNA, FCRLA, FCRLB.
- chr1:169,849,631–173,064,015, 69 genes, copy number 5–9 (within-gene range 2–9) (broad region; genes not listed).
- chr2:203,634,577–204,507,672, 15 genes, copy number 6: AC125238.2, AC125238.1, CD28, KRT18P39, NPM1P33, RNU6-474P, CTLA4, ICOS, AC009965.2, AC009965.1, AC009498.1, DSTNP5, AC106901.1, AC016903.1, AC016903.2.
- chr3:56,727,418–59,754,808, 56 genes, copy number 5 (within-gene range 3–5): ARHGEF3, ARHGEF3-AS1, SPATA12, AC097358.2, IL17RD, AC097358.1, HESX1, APPL1, ASB14, AC093928.1, DNAH12, Y_RNA, RNU6-1181P, RNF7P1, AC092418.1, RNU6-108P, RNU6-483P, AC092418.2, PDE12, ARF4, ARF4-AS1, RNU6ATAC26P, DENND6A, DENND6A-AS1, DENND6A-DT, SLMAP, PDHA1P1, PPIAP16, FLNB, FLNB-AS1, AC137936.1, AC137936.2, DNASE1L3, ABHD6, HTD2, RPP14, AC098479.1, PXK, AC135507.2, PDHB, AC135507.1, AC116036.2, KCTD6, ACOX2, AC116036.1, FAM107A, AC119424.1, FAM3D-AS1, FAM3D, CFAP20DC, CFAP20DC-AS1, AC126121.3, AC138057.1, AC126121.2, AC126121.1, Metazoa_SRP.
- chr3:59,809,269–59,811,310, 1 gene, copy number 5: AC093418.1.
- chr3:133,038,391–198,222,513, 1,129 genes, copy number 6 (within-gene range 3–6) (broad region; genes not listed).
- chr6:1,312,098–1,613,897, 10 genes, copy number 5: FOXQ1, LINC01394, AL034346.1, FOXF2, MIR6720, RN7SL352P, AL512329.1, AL512329.2, FOXCUT, FOXC1.
- chr7:92,112,159–101,252,316, 266 genes, copy number 5–42 (within-gene range 2–42) (broad region; genes not listed).
- chr8:127,253,213–127,742,951, 9 genes, copy number 5: AC018714.2, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, AC108925.1, CASC11, MYC.
- chr11:32,758,268–103,479,863, 1,831 genes, copy number 5–6 (broad region; genes not listed).
- chr12:95,387,890–133,214,832, 937 genes, copy number 5–6 (broad region; genes not listed).
- chr13:18,467,172–103,444,968, 1,228 genes, copy number 5 (broad region; genes not listed).
- chr16:11,555–35,912,516, 1,419 genes, copy number 5 (broad region; genes not listed).
- chr20:87,250–13,996,443, 281 genes, copy number 5 (broad region; genes not listed).
- chr20:14,003,508–14,758,056, 9 genes, copy number 5: RPS3P1, AIMP1P1, RN7SL864P, FLRT3, RNU6-228P, AL121582.1, RNF11P2, MACROD2-IT1, RPS10P2.
- chr20:49,046,246–54,173,986, 104 genes, copy number 5–10 (within-gene range 4–10) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 709. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
